Somatic mutation profile of tumor specimen 38f29517-c046-4da5-ba0d-67d614 (aliquot 38f29517-c046-4da5-ba0d-67d614_D6) from CPTAC case 17OV027, project CPTAC-2 (Retroperitoneum and peritoneum — Cystic, Mucinous and Serous Neoplasms). Sex at birth: female; Primary diagnosis: Serous adenocarcinoma, NOS; Tissue or organ of origin: Peritoneum, NOS.
Specimen 38f29517-c046-4da5-ba0d-67d614: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 53710926-3262-490e-86d4-6fe8253d8f7b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen dc7c7f4c-af59-44eb-ae32-2e4228 (Blood Derived Normal), aliquot dc7c7f4c-af59-44eb-ae32-2e4228_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/146bc42d-05ce-4edb-914b-9c522af42820

The open-access MAF lists 108 somatic variants for this specimen: 78 protein-altering or splice-affecting, 14 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 62, Silent 14, Intron 12, Splice Site 4, Frame Shift Del 4, Nonsense Mutation 3, 5'UTR 2, Splice Region 2, In Frame Del 1, Frame Shift Ins 1, 3'UTR 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 138/284 reads (49%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, varscan2
- AFP | c.138G>A p.L46= | Splice Region (SNP) | VAF 39/140 reads (28%) | catalogued as rs1017306234; called by muse, mutect2, varscan2
- BRCA2 | c.6328G>C p.D2110H | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.902); catalogued as COSV101204731; called by muse, mutect2, varscan2
- CSPP1 | c.1811C>T p.T604M (on ENST00000676605; = p.T563M on NM_024790.6) | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.395); catalogued as rs375847469, COSV51591088; called by muse, mutect2, varscan2
- DLGAP1 | c.1804G>A p.A602T | Missense Mutation (SNP) | VAF 87/297 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.353); catalogued as COSV59801986; called by muse, mutect2, varscan2
- DNAH10 | c.6120G>C p.K2040N (on ENST00000409039; = p.K1979N on NM_207437.3) | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV68991924; called by muse, mutect2, varscan2
- DNAJC2 | c.1060C>T p.Q354* | Nonsense Mutation (SNP) | VAF 14/57 reads (25%) | catalogued as COSV50793126; called by muse, mutect2, varscan2
- EPB41L2 | c.1043A>G p.Y348C | Missense Mutation (SNP) | VAF 130/466 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as rs544017577, COSV61353857; called by muse, mutect2, varscan2
- GOLGA6L4 | c.644T>A p.L215Q | Missense Mutation (SNP) | VAF 35/132 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.029); catalogued as rs201116653; called by muse, varscan2
- KIF5C | c.2819A>G p.H940R | Missense Mutation (SNP) | VAF 47/270 reads (17%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs756273464; called by muse, mutect2, varscan2
- LHFPL2 | c.158C>T p.S53F | Missense Mutation (SNP) | VAF 48/401 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.087); catalogued as rs996445967; called by muse, mutect2, varscan2
- MARS1 | c.1387G>T p.E463* | Nonsense Mutation (SNP) | VAF 48/133 reads (36%) | catalogued as rs1313001176; called by mutect2, varscan2
- NUTM2B | c.545C>G p.P182R | Missense Mutation (SNP) | VAF 203/1339 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1193447925; called by mutect2, varscan2
- PLTP | c.653C>T p.S218F | Missense Mutation (SNP) | VAF 104/402 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs779125405; called by muse, mutect2, varscan2
- PSMC2 | c.694C>T p.R232W | Missense Mutation (SNP) | VAF 61/121 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774084514; called by muse, mutect2, varscan2
- RARRES2 | c.256G>A p.E86K | Missense Mutation (SNP) | VAF 248/413 reads (60%) | SIFT tolerated (0.12); PolyPhen benign (0.062); catalogued as COSV56231702; called by muse, mutect2, varscan2
- RRP12 | c.1391C>T p.P464L | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs146307005; called by muse, mutect2, varscan2
- SEMA4C | c.2464C>G p.P822A | Missense Mutation (SNP) | VAF 48/136 reads (35%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs1355415895; called by muse, mutect2, varscan2
- SLC27A3 | c.1172C>G p.A391G (on ENST00000271857; = p.A263G on NM_024330.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/440 reads (3%) | SIFT tolerated (0.09); PolyPhen benign (0.11); catalogued as rs763843241; called by muse, mutect2
- ZNF257 | c.258C>A p.C86* | Nonsense Mutation (SNP) | VAF 5/27 reads (19%) | catalogued as COSV71311081; called by muse, mutect2
- ABCA2 | c.7211C>A p.T2404K (on ENST00000614293; = p.T2374K on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 106/254 reads (42%) | SIFT tolerated (0.21); PolyPhen benign (0.127); called by mutect2, varscan2
- AGO3 | c.2173-27_2175delinsA p.X725_splice | Splice Site (DEL) | VAF 17/107 reads (16%) | called by pindel, varscan2*
- ANKRD53 | c.671T>G p.L224R | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ANO1 | c.1943T>C p.M648T | Missense Mutation (SNP) | VAF 11/272 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- APBA2 | c.992C>T p.S331F | Missense Mutation (SNP) | VAF 171/565 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- ARHGAP5 | c.710C>A p.T237K | Missense Mutation (SNP) | VAF 50/161 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.646); called by mutect2, varscan2
- B3GNT9 | c.1030C>G p.P344A | Missense Mutation (SNP) | VAF 74/162 reads (46%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.519); called by muse, mutect2, varscan2
- BBOX1 | c.-34_4del | Translation Start Site (DEL) | VAF 34/120 reads (28%) | called by mutect2, pindel, varscan2
- C1GALT1C1 | c.877G>A p.V293I | Missense Mutation (SNP) | VAF 62/126 reads (49%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.523); called by muse, varscan2
- CATSPERE | c.2276C>A p.T759K | Missense Mutation (SNP) | VAF 37/241 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CEP350 | c.4225_4235dup p.L1413Mfs*15 | Frame Shift Ins (INS) | VAF 12/74 reads (16%) | called by mutect2, varscan2
- CNOT11 | c.103G>C p.G35R | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- COG1 | c.98T>C p.L33P | Missense Mutation (SNP) | VAF 64/185 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.683); called by muse, mutect2, varscan2
- CTBP1 | c.1140-8C>A | Splice Region (SNP) | VAF 24/90 reads (27%) | called by muse, mutect2, varscan2
- DCTN1 | c.2315A>G p.Q772R | Missense Mutation (SNP) | VAF 182/624 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- DENND4A | c.2762C>A p.T921K | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.9); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- DNAH2 | c.2654C>A p.T885N | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- DPP4 | c.853A>C p.I285L | Missense Mutation (SNP) | VAF 22/133 reads (17%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- ESPL1 | c.5388G>T p.K1796N | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- FLNA | c.5059_5063del p.T1687Vfs*4 (on ENST00000369850 / NM_001110556.2; = p.T1679Vfs*4 on NM_001456.3) | Frame Shift Del (DEL) | VAF 92/233 reads (39%) | called by mutect2, pindel, varscan2
- GBA3 | c.1315G>T p.D439Y | Missense Mutation (SNP) | VAF 109/358 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- HEATR5B | c.3037G>A p.E1013K | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HKDC1 | c.433C>G p.H145D | Missense Mutation (SNP) | VAF 28/159 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- IL16 | c.614_617del p.P205Lfs*14 | Frame Shift Del (DEL) | VAF 71/230 reads (31%) | called by mutect2, pindel, varscan2
- IMPG1 | c.721T>G p.S241A | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- JAKMIP3 | c.1603-1G>T p.X535_splice | Splice Site (SNP) | VAF 40/88 reads (45%) | called by muse, mutect2, varscan2
- KBTBD7 | c.1742_1746del p.N581Sfs*5 | Frame Shift Del (DEL) | VAF 70/320 reads (22%) | called by mutect2, pindel, varscan2
- KCNQ5 | c.1294G>A p.G432S | Missense Mutation (SNP) | VAF 58/218 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- KDELR3 | c.614G>A p.G205E | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- MAP11 | c.1169A>G p.Y390C | Missense Mutation (SNP) | VAF 45/184 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MYO3B | c.1285del p.D429Tfs*20 | Frame Shift Del (DEL) | VAF 44/189 reads (23%) | called by mutect2, pindel, varscan2
- MYO7A | c.6641G>T p.G2214V | Missense Mutation (SNP) | VAF 50/114 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.067); called by mutect2, varscan2
- NBN | c.984T>A p.H328Q | Missense Mutation (SNP) | VAF 70/265 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- NDUFAF5 | c.153G>C p.L51F | Missense Mutation (SNP) | VAF 43/154 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.573); called by muse, mutect2, varscan2
- NF1 | c.3311_3314+9del p.X1104_splice | Splice Site (DEL) | VAF 6/25 reads (24%) | called by mutect2, pindel, varscan2
- NPAP1 | c.642C>A p.H214Q | Missense Mutation (SNP) | VAF 23/209 reads (11%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.592); called by muse, mutect2
- NPR2 | c.1561G>A p.G521R | Missense Mutation (SNP) | VAF 219/803 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- PADI4 | c.1154_1155+10delinsC p.X385_splice | Splice Site (DEL) | VAF 19/88 reads (22%) | called by pindel, varscan2*
- PHC2 | c.910_933del p.M304_S311del | In Frame Del (DEL) | VAF 57/169 reads (34%) | called by mutect2, pindel, varscan2
- PRELID1 | c.185T>C p.M62T | Missense Mutation (SNP) | VAF 178/601 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- PRKDC | c.10124C>G p.A3375G | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.019); called by muse, varscan2
- PRSS35 | c.565T>G p.L189V | Missense Mutation (SNP) | VAF 94/340 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.844); called by mutect2, varscan2
- RBM20 | c.1241G>T p.C414F | Missense Mutation (SNP) | VAF 72/174 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RCBTB2 | c.1210T>G p.Y404D | Missense Mutation (SNP) | VAF 51/128 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- RTEL1 | c.868G>T p.A290S | Missense Mutation (SNP) | VAF 34/265 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SCAP | c.2506C>G p.R836G | Missense Mutation (SNP) | VAF 80/140 reads (57%) | SIFT tolerated (0.34); PolyPhen benign (0); called by mutect2, varscan2
- SENP3 | c.1212C>A p.D404E | Missense Mutation (SNP) | VAF 6/125 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- SPTLC3 | c.839T>C p.L280P | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TACC3 | c.1111G>A p.A371T | Missense Mutation (SNP) | VAF 77/327 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- TLR4 | c.515C>G p.S172C (on ENST00000355622 / NM_138554.5; = p.S132C on NM_003266.4) | Missense Mutation (SNP) | VAF 136/388 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); called by mutect2, varscan2
- TRIP11 | c.83G>T p.G28V | Missense Mutation (SNP) | VAF 56/236 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- TUBB2A | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 34/131 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.499); called by muse, mutect2, varscan2
- TUBB4B | c.50G>A p.G17D | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TUBB4B | c.82C>A p.H28N | Missense Mutation (SNP) | VAF 43/91 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- UNC93B1 | c.1142C>T p.A381V | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- WDFY4 | c.7967G>A p.C2656Y | Missense Mutation (SNP) | VAF 71/225 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- WFIKKN1 | c.71C>T p.P24L | Missense Mutation (SNP) | VAF 32/231 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZP3 | c.359C>T p.P120L (on ENST00000394857 / NM_001110354.2; = p.P69L on NM_007155.6) | Missense Mutation (SNP) | VAF 42/144 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); called by muse, mutect2, varscan2
- ARHGAP23 | c.2967C>G p.P989= | Silent (SNP) | VAF 37/87 reads (43%) | catalogued as rs928985915; called by muse, mutect2, varscan2
- BAALC | c.405G>A p.Q135= (on ENST00000297574 / NM_001364874.1; = p.Q100= on NM_024812.3) | Silent (SNP) | VAF 45/188 reads (24%) | called by muse, mutect2, varscan2
- CTSO | c.705T>G p.L235= | Silent (SNP) | VAF 15/298 reads (5%) | called by muse, mutect2
- DZANK1 | c.1311C>A p.G437= (on ENST00000262547 / NM_001099407.1; = p.G244= on NM_018152.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 76/250 reads (30%) | called by mutect2, varscan2
- GRIN3A | c.1008G>A p.R336= | Silent (SNP) | VAF 73/596 reads (12%) | catalogued as rs1255981035; called by muse, mutect2, varscan2
- IL18RAP | c.1026C>A p.S342= | Silent (SNP) | VAF 44/153 reads (29%) | called by muse, mutect2, varscan2
- MYH13 | c.2097T>C p.C699= | Silent (SNP) | VAF 62/154 reads (40%) | called by muse, mutect2, varscan2
- NCOR2 | c.171C>T p.S57= | Silent (SNP) | VAF 74/184 reads (40%) | catalogued as rs1468151434; called by muse, mutect2, varscan2
- NELFA | c.363G>A p.L121= (on ENST00000542778; = p.L110= on NM_005663.5) | Silent (SNP) | VAF 40/164 reads (24%) | called by muse, mutect2, varscan2
- PER3 | c.3030A>G p.T1010= | Silent (SNP) | VAF 26/166 reads (16%) | catalogued as rs12023156; called by mutect2, varscan2
- SPATC1 | c.1017C>T p.P339= | Silent (SNP) | VAF 93/164 reads (57%) | catalogued as rs782048859, COSV66298929; called by muse, varscan2
- SYNE4 | c.330C>T p.H110= | Silent (SNP) | VAF 70/249 reads (28%) | called by muse, mutect2, varscan2
- TEP1 | c.3795C>T p.I1265= | Silent (SNP) | VAF 75/287 reads (26%) | catalogued as rs191436526; called by muse, mutect2, varscan2
- ZNF608 | c.1185G>C p.T395= | Silent (SNP) | VAF 16/100 reads (16%) | called by muse, mutect2, varscan2
- ADAM18 | c.-15C>T | 5'UTR (SNP) | VAF 69/261 reads (26%) | catalogued as rs774153416, COSV55849815; called by muse, mutect2, varscan2
- AP001425.1 | chr21:38208407 C>A | 5'Flank (SNP) | VAF 79/300 reads (26%) | called by mutect2, varscan2
- APPL1 | c.1893+43T>C | Intron (SNP) | VAF 29/76 reads (38%) | called by muse, mutect2, varscan2
- C5orf38 | c.*234G>A | 3'UTR (SNP) | VAF 30/90 reads (33%) | catalogued as rs1371032334; called by muse, mutect2
- CYBC1 | c.86-29A>G | Intron (SNP) | VAF 64/235 reads (27%) | called by muse, mutect2, varscan2
- DNA2 | c.3114+23G>C | Intron (SNP) | VAF 32/92 reads (35%) | called by muse, mutect2, varscan2
- EPOR | c.251+221G>A | Intron (SNP) | VAF 27/84 reads (32%) | called by muse, mutect2, varscan2
- GRINA | c.693+82G>A | Intron (SNP) | VAF 40/209 reads (19%) | called by muse, mutect2, varscan2
- MGAM | c.4618+12979A>C | Intron (SNP) | VAF 59/111 reads (53%) | called by muse, mutect2, varscan2
- MYCBPAP | c.364+36C>G | Intron (SNP) | VAF 105/316 reads (33%) | called by muse, mutect2, varscan2
- PAQR6 | c.760+49T>A | Intron (SNP) | VAF 49/174 reads (28%) | called by muse, mutect2, varscan2
- PILRB | c.-217-85C>T | Intron (SNP) | VAF 110/295 reads (37%) | called by muse, mutect2, varscan2
- PTCH2 | c.-12A>G | 5'UTR (SNP) | VAF 14/42 reads (33%) | called by muse, mutect2, varscan2
- SHROOM3 | c.4710-31_4710-30insCTC | Intron (INS) | VAF 13/49 reads (27%) | catalogued as rs769241594; called by pindel, varscan2*
- SLCO1B3-SLCO1B7 | c.1866-45849T>C | Intron (SNP) | VAF 31/96 reads (32%) | catalogued as rs1342088518; called by muse, mutect2, varscan2
- STARD10 | c.207+596G>T | Intron (SNP) | VAF 31/157 reads (20%) | called by muse, mutect2, varscan2
